Somatic mutation profile of tumor specimen TCGA-06-2570-01A (aliquot TCGA-06-2570-01A-01D-1495-08) from TCGA case TCGA-06-2570, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 21.7 years (7,936 days).
Specimen TCGA-06-2570-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d58e28b2-7018-496a-b8f8-97446e57d25d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-2570-10A (Blood Derived Normal), aliquot TCGA-06-2570-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c978002-6e44-491b-beaf-f1b87e6c2c1b

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 23, Silent 8, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 72/158 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1625A>T p.E542V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1057519927, COSV55876800, COSV55881194, COSV55893680; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.406C>G p.Q136E | Missense Mutation (SNP) | VAF 63/72 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1555526268, CM971503, COSV52676850, COSV52715987, COSV52740951; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMBRA1 | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 79/102 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54048486; called by muse, mutect2, varscan2
- CDKL5 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 73/109 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV66110209; called by muse, mutect2, varscan2
- CHRND | c.251C>A p.T84K | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV51317359; called by muse, mutect2, varscan2
- CRACDL | c.2383A>G p.T795A | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV67406498; called by muse, mutect2, varscan2
- DNAI4 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV64021515; called by muse, mutect2, varscan2
- ELOVL7 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70917532; called by muse, mutect2, varscan2
- FLG | c.8707G>A p.D2903N | Missense Mutation (SNP) | VAF 236/1169 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.878); catalogued as rs1164616983, COSV64236448; called by muse, mutect2, varscan2
- INTS5 | c.1410G>T p.L470F | Missense Mutation (SNP) | VAF 62/83 reads (75%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV57950277; called by muse, mutect2, varscan2
- IRAK3 | c.181T>C p.Y61H | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as COSV54159388; called by muse, mutect2, varscan2
- KRTAP12-4 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs782538322, COSV59951725; called by mutect2, varscan2
- LRRC6 | c.1270T>A p.S424T | Missense Mutation (SNP) | VAF 30/303 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.835); catalogued as COSV51540718; called by muse, mutect2, varscan2
- MLH3 | c.2132C>G p.S711C | Missense Mutation (SNP) | VAF 148/319 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV53152230; called by muse, mutect2, varscan2
- NDRG1 | c.815G>A p.C272Y | Missense Mutation (SNP) | VAF 97/211 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60482447; called by muse, mutect2, varscan2
- PLD4 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs371620185, COSV66915132; called by muse, mutect2, varscan2
- RASEF | c.1666A>G p.S556G | Missense Mutation (SNP) | VAF 102/226 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375201668; called by muse, mutect2, varscan2
- RUFY4 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs369707895, COSV60247232; called by muse, mutect2, varscan2
- SLC35G3 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 107/264 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs758758294, COSV52010173; called by muse, mutect2, varscan2
- TSPEAR | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV100553540; called by muse, mutect2
- TSPEAR | c.127G>C p.G43R | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as COSV100553541; called by muse, mutect2
- ZNF81 | c.1474C>A p.H492N | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58575882; called by muse, mutect2, varscan2
- ATRX | c.4269_4272del p.K1424Gfs*65 | Frame Shift Del (DEL) | VAF 78/104 reads (75%) | called by mutect2, pindel, varscan2
- ABCB4 | c.1680G>A p.T560= | Silent (SNP) | VAF 85/202 reads (42%) | catalogued as rs1256259988, COSV55931950; called by muse, mutect2, varscan2
- CDH4 | c.2049C>T p.A683= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as rs201703403, COSV64644716; called by muse, mutect2
- KCNK4 | c.219G>A p.A73= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as rs777814993, COSV60453536; called by muse, mutect2, varscan2
- LARGE2 | c.318T>C p.H106= | Silent (SNP) | VAF 35/50 reads (70%) | catalogued as COSV57683944, COSV57684002; called by muse, mutect2, varscan2
- MAP3K1 | c.2871A>G p.Q957= | Silent (SNP) | VAF 74/167 reads (44%) | catalogued as COSV68121758; called by muse, mutect2, varscan2
- OR2W3 | c.717C>T p.G239= | Silent (SNP) | VAF 117/270 reads (43%) | catalogued as rs1333729929, COSV64456031; called by muse, mutect2, varscan2
- P3H2 | c.2025T>C p.Y675= | Silent (SNP) | VAF 113/230 reads (49%) | catalogued as rs578158144, COSV60017874; called by muse, mutect2, varscan2
- RIF1 | c.6597T>C p.N2199= | Silent (SNP) | VAF 89/216 reads (41%) | catalogued as COSV54612394; called by muse, mutect2, varscan2
